Somatic mutation profile of tumor specimen MBCProject_2200_T1_WES (aliquot MBCProject_2200_T1_WES_1) from CMI case MBCProject_2200, project CMI-MBC: Count Me In (CMI): The Metastatic Breast Cancer (MBC) Project. Sex at birth: female; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; Age at diagnosis: 48.8 years (17,830 days).
Specimen MBCProject_2200_T1_WES: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Breast; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1f401745-18f4-45fd-919e-33fb11384f5a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MBCProject_2200_SALIVA (Saliva), aliquot MBCProject_2200_SALIVA_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/062eb583-9395-4182-a6aa-fc140abb02cc

The open-access MAF lists 42 somatic variants for this specimen: 27 protein-altering or splice-affecting, 9 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 22, Silent 9, Intron 2, 3'UTR 2, Splice Region 2, Translation Start Site 1, 3'Flank 1, Nonsense Mutation 1, Frame Shift Del 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.725G>C p.C242S | Missense Mutation (SNP) | VAF 40/254 reads (16%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121912655, CM910618, COSV52661189, COSV52677418, COSV52689710; called by muse, mutect2, varscan2
- CNGB3 | c.1094A>G p.H365R | Missense Mutation (SNP) | VAF 30/356 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100181972; called by muse, mutect2
- INTS6L | c.961A>G p.M321V | Missense Mutation (SNP) | VAF 10/117 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.1); catalogued as rs1354399963; called by muse, mutect2, varscan2
- MUC16 | c.11170C>T p.P3724S | Missense Mutation (SNP) | VAF 8/102 reads (8%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); catalogued as rs1331207547; called by muse, mutect2
- NRDE2 | c.1185G>A p.W395* | Nonsense Mutation (SNP) | VAF 20/156 reads (13%) | catalogued as rs1349824005; called by muse, mutect2, varscan2
- OR6Y1 | c.641T>C p.I214T | Missense Mutation (SNP) | VAF 15/90 reads (17%) | SIFT tolerated (0.22); PolyPhen benign (0.122); catalogued as COSV56930279; called by muse, mutect2, varscan2
- PCDHA7 | c.211C>T p.R71C | Missense Mutation (SNP) | VAF 33/409 reads (8%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.891); catalogued as rs1383001934, COSV65343356; called by muse, mutect2
- PEX5 | c.598G>A p.D200N | Missense Mutation (SNP) | VAF 42/335 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.013); catalogued as rs758801966; called by muse, mutect2, varscan2
- PINLYP | c.422T>C p.M141T | Missense Mutation (SNP) | VAF 22/161 reads (14%) | SIFT tolerated (0.63); PolyPhen benign (0.294); catalogued as rs907936005; called by muse, mutect2, varscan2
- SLC12A9 | c.2627C>T p.P876L | Missense Mutation (SNP) | VAF 20/204 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs578048987; called by muse, mutect2
- SRPK3 | c.302G>A p.R101H | Missense Mutation (SNP) | VAF 14/124 reads (11%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.884); catalogued as rs782011345; called by muse, mutect2
- TMEM119 | c.356G>A p.R119Q | Missense Mutation (SNP) | VAF 28/241 reads (12%) | SIFT deleterious (0.05); PolyPhen benign (0.288); catalogued as rs777700211, COSV67188350; called by muse, mutect2, varscan2
- ANKRD24 | c.322G>T p.V108F | Missense Mutation (SNP) | VAF 15/62 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.765); called by muse, mutect2, varscan2
- ARHGEF1 | c.1880T>G p.L627R | Missense Mutation (SNP) | VAF 42/256 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- BUB1 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 16/237 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.954); called by muse, mutect2
- CEP131 | c.191del p.P64Lfs*36 | Frame Shift Del (DEL) | VAF 35/171 reads (20%) | called by mutect2, pindel, varscan2
- GAS2L2 | c.735G>A p.R245= | Splice Region (SNP) | VAF 17/135 reads (13%) | called by muse, mutect2, varscan2
- GIGYF1 | c.730G>A p.G244R | Missense Mutation (SNP) | VAF 6/62 reads (10%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.809); called by muse, mutect2, varscan2
- GUCY1B2 | n.682C>G | Splice Region (SNP) | VAF 8/77 reads (10%) | called by muse, mutect2, varscan2
- KLHL12 | c.1519A>G p.T507A | Missense Mutation (SNP) | VAF 8/139 reads (6%) | SIFT tolerated (0.16); PolyPhen benign (0.003); called by muse, mutect2
- KLRC3 | c.154C>T p.H52Y | Missense Mutation (SNP) | VAF 21/167 reads (13%) | SIFT tolerated (0.49); PolyPhen benign (0.146); called by muse, mutect2, varscan2
- POU2F2 | c.1147G>A p.G383S (on ENST00000526816 / NM_001207025.3; = p.G367S on NM_002698.5) | Missense Mutation (SNP) | VAF 6/92 reads (7%) | SIFT tolerated (1); PolyPhen benign (0.062); called by muse, mutect2
- RSBN1 | c.716A>G p.E239G | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.991); called by muse, mutect2
- SHISAL2B | c.392C>T p.A131V | Missense Mutation (SNP) | VAF 20/251 reads (8%) | SIFT tolerated (0.23); PolyPhen benign (0.003); called by muse, mutect2
- SUPT20H | c.949T>A p.S317T (on ENST00000350612 / NM_001014286.3; = p.S318T on NM_017569.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 9/151 reads (6%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.573); called by muse, mutect2
- TOP2B | c.1898A>G p.Y633C (on ENST00000264331 / NM_001330700.2; = p.Y628C on NM_001068.3) | Missense Mutation (SNP) | VAF 8/83 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZMYM4 | c.193T>G p.S65A | Missense Mutation (SNP) | VAF 16/266 reads (6%) | SIFT tolerated, low confidence (0.38); PolyPhen possibly damaging (0.899); called by muse, mutect2
- CA7 | c.627C>G p.V209= | Silent (SNP) | VAF 6/82 reads (7%) | called by muse, mutect2
- CHRNA4 | c.669C>T p.Y223= | Silent (SNP) | VAF 24/324 reads (7%) | catalogued as rs79068736, COSV100937361; ClinVar: likely benign; called by muse, mutect2
- HBS1L | c.663G>A p.T221= | Silent (SNP) | VAF 36/574 reads (6%) | catalogued as rs750935367; called by muse, mutect2
- KIAA0825 | c.2721C>G p.T907= | Silent (SNP) | VAF 36/175 reads (21%) | catalogued as COSV101449483; called by muse, mutect2, varscan2
- OR5T1 | c.831C>T p.S277= | Silent (SNP) | VAF 24/141 reads (17%) | called by muse, mutect2, varscan2
- THBS1 | c.3114G>A p.V1038= | Silent (SNP) | VAF 43/538 reads (8%) | catalogued as rs779416913; called by muse, mutect2
- TTLL8 | c.1404C>T p.P468= | Silent (SNP) | VAF 24/152 reads (16%) | catalogued as rs753536482; called by muse, mutect2, varscan2
- TTN | c.48819G>A p.K16273= (on ENST00000591111; = p.K8849= on NM_003319.4) | Silent (SNP) | VAF 10/200 reads (5%) | called by muse, mutect2
- ZNF23 | c.924C>T p.Y308= | Silent (SNP) | VAF 15/131 reads (11%) | catalogued as rs142314445; called by muse, mutect2, varscan2
- ACBD5 | chr10:27195945 C>G | 3'Flank (SNP) | VAF 6/52 reads (12%) | catalogued as rs1475586677; called by muse, mutect2
- CSF2RA | c.*44G>A | 3'UTR (SNP) | VAF 18/304 reads (6%) | catalogued as rs781308302, COSV100817592; called by muse, mutect2
- KLHL7 | c.*1072T>C | 3'UTR (SNP) | VAF 11/136 reads (8%) | called by muse, mutect2
- POM121L9P | n.896G>A | RNA (SNP) | VAF 31/464 reads (7%) | catalogued as rs757152596; called by muse, mutect2
- SNED1 | c.3817+106C>T | Intron (SNP) | VAF 6/66 reads (9%) | catalogued as rs1350280582, COSV100122762; called by muse, mutect2
- TNK2 | c.-18-3806C>T | Intron (SNP) | VAF 13/109 reads (12%) | called by muse, mutect2, varscan2
